Somatic mutation profile of tumor specimen ALCH-AFG5-TTP1-A (aliquot ALCH-AFG5-TTP1-A-1-0-D-A678-36) from ALCHEMIST case ALCH-AFG5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.2 years (18,684 days).
Specimen ALCH-AFG5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0d5010b-575a-40d7-8c7f-dee085ef5315.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFG5-NB1-A (Blood Derived Normal), aliquot ALCH-AFG5-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/786a4a2e-d729-43d1-9764-2ccace2b1a9a

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 6/139 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2
- GIMAP4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 49/402 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs778778849, COSV99750489; called by muse, mutect2, varscan2
- KLHL21 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as COSV66554343; called by muse, mutect2, varscan2
- LBP | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764270327, COSV54142290, COSV99461108; called by muse, mutect2
- OR9G4 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs142667643; called by muse, mutect2, varscan2
- ABCA9 | c.2872G>A p.G958S | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- AKR7L | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC82 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CX3CL1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FGD6 | c.1322A>G p.D441G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- GABRP | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- RTKN2 | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SMIM29 | c.77G>A p.R26Q (on ENST00000394990 / NM_001008704.3; = p.R46Q on NM_178508.5) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SOX4 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TANGO6 | c.1640T>G p.I547S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- TKFC | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.098); called by muse, mutect2
- TRPM2 | c.3190A>G p.K1064E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNRF3 | c.2354A>G p.K785R (on ENST00000544604 / NM_001206998.2; = p.K685R on NM_032173.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CFAP157 | c.918G>A p.E306= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs756189594; called by muse, mutect2
- GLT6D1 | c.348C>T p.D116= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs754546707, COSV65627677; called by muse, mutect2, varscan2
- SORCS3 | c.2643C>T p.H881= | Silent (SNP) | VAF 23/380 reads (6%) | catalogued as rs375407867; called by muse, mutect2
- SOWAHC | c.930C>G p.A310= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- ATG2B | chr14:96276160 C>A | 3'Flank (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5579G>A | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs767068056; called by muse, mutect2, varscan2
- MARCHF1 | c.163-34C>A | Intron (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- ZNF778 | c.*4279A>G | 3'UTR (SNP) | VAF 18/182 reads (10%) | catalogued as rs1270021352; called by muse, varscan2
